TCGA case TCGA-10-0926 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: MD Anderson Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e641aed9-1dd8-4c30-b231-f12b20a76df0

Demographics
Sex at birth: female; Race: white; Age at index: 63 years; Vital status: Dead; Days to death: 788 days (2.2 years).

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 63.8 years (23,307 days); Year of diagnosis: 2000; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC; Tumor grade: G3; Prior treatment: No.
   Pathology details: Lymphatic invasion present: No; Residual tumor measurement: 11-20 mm; Vascular invasion present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Initial disease status: Progressive Disease; Days to treatment start: 8 days; Days to treatment end: 143 days; Number of cycles: 6; Treatment dose: 4,500 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Initial disease status: Progressive Disease; Days to treatment start: 8 days; Days to treatment end: 143 days; Number of cycles: 6; Treatment dose: 860 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Recombinant Interleukin-12; Treatment intent type: Adjuvant; Initial disease status: Progressive Disease; Days to treatment start: 232 days; Treatment dose: 22,920 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment start: 273 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Initial disease status: Recurrent Disease; Days to treatment start: 290 days; Days to treatment end: 729 days (2.0 years); Number of cycles: 13; Treatment dose: 975 mg; Route of administration: Intravenous.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 64.6 years (23,594 days); Days to diagnosis: 287 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 287 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 287 days; Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 788 days (2.2 years); Disease response: With Tumor.
- Karnofsky performance status: 80; Timepoint: Preoperative.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-10-0926-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1; Intermediate dimension: 0.8; Shortest dimension: 0.6.
  Slide TCGA-10-0926-01A-01-BS1: Section location: Bottom; Percent tumor cells: 98; Percent tumor nuclei: 99; Percent normal cells: 2; Percent necrosis: 0; Percent stromal cells: 0.
  Slide TCGA-10-0926-01A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 99; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 0.
- Sample TCGA-10-0926-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Lymphovascular invasion indicator: No.
- Drug treatment 1: Pharmaceutical therapy drug name: Doxil.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Pharmaceutical therapy drug name: Taxol; Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: Adjuvant and Progression.
- Drug treatment 3: Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: Ajuvant and Progression.
- Drug treatment 4: Pharmaceutical therapy drug name: Interleukin-12; Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: Adjuvant and Progression.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 788 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 788 days; disease-free interval: event (new tumor event after initially disease-free), 287 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 287 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-10-0926-01A-01D-0399-01): tumor purity 0.87, ploidy 2.84, whole-genome doublings 1.
